Gene-level copy-number profile of tumor specimen C3L-02202-01 from CPTAC case C3L-02202, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G1; Age at diagnosis: 61.9 years (22,609 days).
Specimen C3L-02202-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 800a5d5a-e313-423f-b039-6f2973dfd7eb.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-02202-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,737 have no estimate.
https://portal.gdc.cancer.gov/files/93670376-9ab8-49fd-bb4e-549d689de454

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 520; copy number 1: 5,566; copy number 2: 47,732; copy number 3: 5,068.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–143,450,245, 3 genes: AC239859.5, RNA5SP533, AC239859.3.
- chr21:8,680,538–8,680,934, 1 gene: CR381572.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 3,227. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
